Gene-level copy-number profile of tumor specimen TCGA-B7-5818-01A from TCGA case TCGA-B7-5818, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.4 years (22,792 days).
Specimen TCGA-B7-5818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.50d73e90-628f-4a3c-bad7-0aca989b6f6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B7-5818-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2b76cc8-eb36-4f1b-bb66-09bb632fe646

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,715; copy number 2: 45,368; copy number 3: 7,912; copy number 4: 827; copy number 5: 974; copy number 10: 8; copy number 35: 12; copy number 42: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B7-5818-01A-11D-1599-01): tumor purity 0.71, ploidy 2.15, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 997 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,944,428–198,222,513, 974 genes, copy number 5 (broad region; genes not listed).
- chr11:34,915,829–35,020,591, 1 gene, copy number 35 (within-gene range 2–35): PDHX.
- chr11:35,132,655–35,620,865, 11 genes, copy number 35: AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1.
- chr11:38,498,995–38,686,323, 3 genes, copy number 42: AC021713.1, LINC02759, LINC01493.
- chr17:37,609,739–37,884,743, 8 genes, copy number 10 (within-gene range 3–10): AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7.

Autosomal genes at a single copy (total copy number 1): 2,912. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
